Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-A61G, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-A61G-01A (Primary Tumor).

[page 1 of 6]
DOB: [Redacted] Age: [Redacted]
Gender: M

Collected:
Received:

Pathologic Interpretation:

A. LEFT NECK LEVEL 5 LYMPH NODE:

No carcinoma seen in one lymph node.

B. MIDDLE SUPRAHYOID:

No malignancy seen.

C. LEFT SUPRAHYOID:

No malignancy seen.

D. RIGHT SUPRAHYOID:

No malignancy seen.

E. FLOOR OF MOUTH:

No malignancy seen.

F. RIGHT FLOOR OF MOUTH:

No malignancy seen.

G. LEFT LATERAL BORDER OF TONGUE:

No malignancy seen.

H. RIGHT POSTERIOR BORDER OF TONGUE:

No malignancy seen.

I. MIDDLE DEEP TONGUE:

No malignancy seen.

J. RIGHT LATERAL BORDER OF TONGUE:

No malignancy seen.

K. MANDIBLE, BILATERAL NECK DISSECTION LEVEL 1-3:

INVASIVE MODERATELY DIFFERENTIATED KERATINIZING SQUAMOUS CELL CARCINOMA, 5.3 cm in greatest dimension.

The carcinoma arises at the mucosa of floor of mouth and invades underlying connective tissue, salivary gland, and bone.

Soft tissue resection margins are negative.

*ICD-O-3
Carcinoma, squamous cell,
keratinizing NOS 8071/3
Site: Floor of mouth NOS
004.9
JAD 5/14/13*

[page 2 of 6]
Bone resection margins are pending decalcification.

Perineural invasion is present.

Metastatic carcinoma is present in five of thirteen lymph nodes (5/13), is present in both right and left cervical lymph nodes, with focal extracapsular extension.

AJCC: pT4a, N2c, Mn/a

See complete Tumor Summary below.

Note: Precise tumor staging requires integration of clinical and radiographic findings.

L. LEFT LEVEL 5 LYMPH NODE:

Eleven lymph nodes, no malignancy seen (0/11).

M. RIGHT LEVEL 5 LYMPH NODE:

Ten lymph nodes, no malignancy seen (0/10).

N. RIGHT LEVEL 2B LYMPH NODE:

Four lymph nodes, no malignancy seen (0/4).

O. LEFT SIDE LEVEL 1A:

Salivary gland and surrounding fibroadipose tissue, no malignancy seen.

Surgical Pathology Cancer Case Summary

Specimen: Floor of mouth

Received: In formalin

Procedure:

Resection: Mandibulectomy: Floor of mouth, mandible

Neck (lymph node) dissection: Bilateral

Specimen Integrity: Intact

Specimen Size:

Greatest dimensions: 12 x 9.4 x 2 cm

Specimen Laterality: Midline

Tumor Site: Floor of mouth, NOS

Tumor Focality: Single focus

Tumor Size: Greatest dimension: 5.3 cm

Histologic Type: Squamous cell carcinoma, conventional

Histologic Grade: G2: Moderately differentiated

Margins:

Margins uninvolved by invasive carcinoma (soft tissue; bone margins are pending decalcification and results will follow as an addendum)

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Present

Lymph Nodes, Extranodal Extension: Present

Pathologic Staging (pTNM):

Primary Tumor (pT):

pT4a: Moderately advanced local disease

Regional Lymph Nodes (pN):

pN2c: Metastasis in bilateral or contralateral lymph nodes, none more than 6 cm in greatest dimension

Number of Lymph Nodes Examined: 39

Number of Lymph Nodes Involved: 5

Distant Metastasis (pM):

Distant Metastasis

[page 3 of 6]
immunohistochemical stains are used with formalin or molecular fixed, paraffin embedded tissue. Detection is by Envision Method. The results are read by a pathologist as positive or negative.

Electronically Signed Out By

Addendum Diagnosis

- K. Keratin immunostain was used to confirm involvement in one lymph node by metastatic carcinoma. The original interpretation remains unchanged.

Intraoperative Consultation

AFS. Left neck level 5 lymph node: No carcinoma seen in one lymph node.

BFS. Middle supra hyoid: No malignancy seen

CFS. Left supra hyoid: No malignancy seen

DFS. Right supra hyoid: No malignancy seen

EFS. Floor of mouth: No malignancy seen

FFS. Right floor of mouth: No malignancy seen

FSG. Left lateral border of tongue: No malignancy seen

HFS. Right posterior border of tongue: No malignancy seen

IFS. Middle deep tongue: No malignancy seen

JFS. Right lateral border of tongue: No malignancy seen

Clinical History:

None provided

Operation Performed

Resection of mandible, tracheostomy, pectoralis flap bilateral neck dissection

Pre Operative Diagnosis:

Squamous cell carcinoma

[page 4 of 6]
Specimen(s) Received/Processing Information:

Fee Codes:

A: LEFT NECK LEVEL 5 LYMPH NODE *Frozen section x 1, FS Perm x 1, Touch Prep Histology x 1*

B: MIDDLE SUPRAHYOID *Frozen section x 1, FS Perm x 1*

C: LEFT SUPRAHYOID *Frozen section x 1, FS Perm x 1*

D: RIGHT SUPRAHYOID *Frozen section x 1, FS Perm x 1*

E: FLOOR OF MOUTH *Frozen section x 1, FS Perm x 1*

F: RIGHT FLOOR OF MOUTH *Frozen section x 1, FS Perm x 1*

G: LEFT LATERAL BORDER OF TONGUE *Frozen section x 1, FS Perm x 1*

H: RIGHT POSTERIOR BORDER OF TONGUE *Frozen section x 1, FS Perm x 1*

I: MIDDLE DEEP TONGUE Frozen section x 1, FS Perm x 1

J: RIGHT LATERAL BORDER OF TONGUE *Frozen section x 1, FS Perm x 1, FSDeep 1 x 1*

[illegible]

L: LEFT LEVEL 5 LYMPH NODE H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1

M: RIGHT LEVEL 5 LYMPH NODE H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1

N: RIGHT LEVEL 2B LYMPH NODE H&E, Initial x 1, H&E, Initial x 1

O: LEFT SIDE LEVEL 1A H&E, Initial x 1

Gross Description:

A. Received fresh label as "left neck level 5 lymph node" is a tan brown soft tissue fragment (1.2 x 0.7 x 0.2 cm. The specimen is submitted in toto in one cassette for frozen section.

B. Received fresh labeled as "middle supra hyoid" is a brown soft tissue fragment (1.0 x 0.7 x 0.3 cm). The specimen is submitted in toto in one cassette for frozen section.

C. Received fresh labeled as "left supra hyoid" is a brown soft tissue fragment (1.2 x 1.0 x 0.2 cm). The specimen is submitted in toto in one cassette for frozen section.

[page 5 of 6]
- D. Received fresh labeled as "right supra hyoid" is a brown soft tissue fragment (0.7 x 0.6 x 0.2 cm). The specimen is submitted in toto in one cassette for frozen section.
- E. Received fresh labeled as "floor of mouth" is a tan soft tissue fragment (1.0 x 0.7 x 0.3 cm). The specimen is submitted in toto in one cassette for frozen section.
- F. Received fresh labeled as "right floor of mouth" is a tan brown soft tissue fragment (0.9 x 0.4 x 0.2 cm). The specimen is submitted in toto in one cassette for frozen section.
- G. Received fresh labeled as "left lateral border of tongue" is a tan brown soft tissue fragment (0.7 x 0.6 x 0.1 cm). The specimen is submitted in toto in one cassette for frozen section.
- H. Received fresh labeled as "right posterior border of tongue" is a brown soft tissue fragment measuring 1.0 x 0.7 x 0.1 cm. The specimen is submitted in toto in one cassette for frozen section.
- I. Received fresh labeled as "middle deep tongue" is a brown soft tissue fragment (0.6 x 0.5 x 0.2 cm). The specimen is submitted in toto in one cassette for frozen section.
- J. Received fresh labeled as "right lateral border of tongue" is one segment of tan brown soft tissue, measuring 0.7 x 0.5 x 0.1 cm. The specimen is submitted in toto in one cassette for frozen section.
- K. Received in formalin labeled as "mandible bilateral neck dissection level 1-3" is an unoriented segment of mandible (8.0 x 7.3 x 3.6 cm) with attached fibromuscular tissue (12.0 x 9.4 x 2.0 cm consisting of an attached arbitrarily designated submandibular gland (left) (3.2 x 3.0 x 4.0 cm) and arbitrarily designated submandibular gland (right) (3.8 x 1.5 x 3.2 cm). The floor of mouth measures 1.5 x 3.0 x 1.1 cm. The soft tissue of the exterior surface measures 14 x 3.5 cm in height. Both bone resection margins are smooth with the arbitrarily designated left bone resection margin void of soft tissue for 0.7 cm and 0.6 cm on the right aspect. The anterior soft tissue margin is inked black. The inferior margin is inked green and the floor of mouth is inked yellow. There is a well circumscribed fungating red brown mass located at the floor of the mouth (5.3 x 1.2 cm). Sectioning of the anterior soft tissue margin reveals a the tumor extending on the right lateral aspect located 0.5 cm from the soft tissue resection margin, 0.5 cm from the left soft tissue margin and 0.8 cm the inferior margin. On the posterior aspect the tumor is located 0.4 cm from the resection margin and appears to grossly involve the salivary gland. On the left aspect of the neck dissection in arbitrarily designated level 1 is a possible lymph node (3.0 cm in length x 1.4 cm in diameter and adjacent to the submandibular gland which grossly appears uninvolved of tumor. An additional lymph node was found in level 1 measuring 1.8 x 1.0 x 0.6 cm. Located in arbitrarily designated level II are two possible lymph nodes (2.1 x 1.1 x 0.6 cm and 1.1 x 0.7 x 0.5 cm. Located in arbitrarily designated level III are three possible lymph nodes, ranging from 1.1 to 0.5 x 0.3 cm to 1.5 x 0.8 x 0.5 cm. Located on the right side is a possible lymph node with a multilocular cut surface (3.0 cm in length x 1.6 cm in diameter adjacent to the submandibular gland. Sectioning of arbitrarily designated level I reveals an additional lymph node (0.6 x 0.6 x 0.4 cm). Sectioning of arbitrarily designated level 2 reveals three possible lymph nodes ranging from 1.5 x 0.9 x 0.6 cm to 0.5 x 1.1 x 0.5 cm and two possible lymph nodes (1.6 x 0.5 x 0.5 cm and 1.5 x 0.6 x 0.5 cm) in level 3. Representative sections are as follows:
- | | |
|----------------|---|
| Cassette 1 | Right soft tissue resection margin with tumor |
| Cassette 2 | Anterior resection margin |
| Cassette 3 | Left anterior resection margin with tumor |
| Cassette 4 | Inferior margin |
| Cassette 5-7 | Tumor in relation to inferoposterior margins |
| Cassette 8 | right submandibular glands with lymph node |
| Cassette 9 | Left submandibular gland |
| Cassette 10 | Right level I one lymph node bisected |
| Cassette 11 | Level I one lymph node cross section (right) |
| Cassette 12 | Two level II lymph nodes bivalve (right) |
| Cassette 13 | One level II lymph nodes bivalve (right) |
| Cassette 14 | One lymph node bivalve) |
| Cassette 15 | One possible lymph node |
| Cassette 16 | Left aspect level I one lymph node cross section |
| Cassette 17 | Level I one lymph node trisected |
| Cassette 18 | Level II one lymph node bivalve |
| Cassette 19 | Level II one lymph node bivalve |
| Cassette 20 | Level III two lymph nodes bivalve |
| Cassette 21 | Right bone resection margin submitted for decalcification |
| Cassette 22 | Left bone resection margin submitted for decalcification |
| Cassette 23&24 | Bone and tumor invasion |

L. Received in formalin labeled "left level 5 lymph node" is a yellow pink segment of fibroadipose tissue (4.7 x 1.8 x 1.1 cm). No lymph nodes are grossly identified. The specimen is submitted in toto in seven cassettes.

M. Received in formalin labeled "right level 5 lymph node" is a pink yellow segment of fibroadipose tissue (8.0 x 1.7 x 0.8 cm). Sectioning reveals eleven possible lymph nodes ranging from 0.1 x 0.1 x 0.1 cm to 1.5 x 1.0 x 0.9 cm. All lymph nodes are

[page 6 of 6]
submitted in toto in five cassettes.

Cassette 1	Two lymph nodes bivalved
Cassette 2	Two lymph nodes bivalved
Cassette 3	One lymph node bisected
Cassette 4	Three whole lymph nodes, one inked green and one inked black
Cassette 5	Two whole lymph nodes, one inked green

N. Received in formalin labeled "right level 2B lymph node" is one segment of tan pink fibroadipose tissue (2.1 x 1.2 x 0.7 cm). Six possible lymph nodes are identified ranging from 0.2 to 0.2 to 0.7 x 0.6 x 0.6 cm. These lymph nodes are submitted in toto in two cassettes as follows:

Cassette 1	Three whole lymph nodes (one inked black, one inked green)
Cassette 2	Three lymph nodes bivalved

O. Received in formalin labeled "left side level A1" is a possible lymph node with attached adipose tissue (1.5 x 1.0 x 0.4 cm). The specimen is bisected and submitted in toto in one cassette.

Source: NCI Genomic Data Commons file 38f922d1-ae3b-4c26-abdb-ede931bf249e (TCGA-IQ-A61G.B2E47F00-0453-4213-A211-9F2C500537C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).